Somatic mutation profile of tumor specimen BLGSP-71-06-00342-01A (aliquot BLGSP-71-06-00342-01A-01D-A663-33) from CGCI case BLGSP-71-06-00342, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 9.5 years (3,454 days).
Specimen BLGSP-71-06-00342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c2aa3dd-040a-4269-b697-b1084d958ee7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00342-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00342-12A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d53b972-0fc6-419b-b055-5dccb7a68b66

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs749972738, COSV54107754, COSV99512845; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 49/51 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.595dup p.Q199Pfs*201 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | called by pindel, varscan2
- DDX3X | c.1654A>C p.T552P (on ENST00000399959; = p.T553P on NM_001356.5) | Missense Mutation (SNP) | VAF 311/342 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- GNAI2 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 156/336 reads (46%) | called by pindel, varscan2
- H2BC21 | c.307C>T p.L103= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, varscan2
- MALRD1 | c.84T>G p.S28= | Silent (SNP) | VAF 52/674 reads (8%) | called by muse, mutect2
- MYC | c.295C>T p.L99= (on ENST00000377970; = p.L114= on NM_002467.6) | Silent (SNP) | VAF 104/234 reads (44%) | catalogued as COSV52380433, COSV99420109; called by muse, mutect2, varscan2
- MYC | chr8:127736039 C>T | 5'Flank (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
- MYC | c.-326G>A | 5'UTR (SNP) | VAF 25/58 reads (43%) | catalogued as rs1315130581; called by muse, mutect2, varscan2
